Surgical pathology report (de-identified scan), TCGA case TCGA-49-4494, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4494-01A (Primary Tumor).

FINAL DIAGNOSIS -----

1. R10 LYMPH NODE (RESECTION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.
2. LUNG, LEFT UPPER LOBE (LOBECTOMY): MODERATELY-DIFFERENTIATED MUCINOUS ADENOCARCINOMA OF THE LUNG (2.5 CM) WITH FOCI OF NECROSIS. TUMOR EXTENDS TO THE PLEURA. BRONCHIAL AND VASCULAR MARGINS ARE NEGATIVE FOR TUMOR. TWO (2) OF FOUR (4) REGIONAL LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA. UNINVOLVED LUNG SHOWS HEMORRHAGE EXTENSIVE REMOLDING, SUBPLEURAL SCARRING AND ACUTE AND CHRONIC INFLAMMATION.
3. LYMPH NODE, AP WINDOW (RESECTION): ONE (1) LYMPH NODE POSITIVE FOR METASTATIC ADENOCARCINOMA.

Source: NCI Genomic Data Commons file b9d86cc7-9edf-4e03-ab7b-288554f38a9a (TCGA-49-4494.178A8648-F3CD-46AE-B90A-A45D6715C889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).